CPTAC case C3N-01877 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d3953640-1289-45a1-9db2-61283f586a50

Demographics
Sex at birth: female; Race: white; Year of birth: 1943; Vital status: Dead; Days to death: 912 days (2.5 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 73.9 years (27,005 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 912 days (2.5 years); Progression or recurrence: no; Days to last follow up: 678 days (1.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 8 cm; Lymph node involvement: Positive; Lymph nodes positive: 5; Lymph nodes tested: 22; Margin status: Involved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 397 days (1.1 years); Disease response: With Tumor; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 678 days (1.9 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 195 days; Karnofsky performance status: 60; ECOG performance status: 3.

Other clinical attributes
- Weight: 100 kg; Height: 163 cm; BMI: 37; Hormonal contraceptive use: Never Used.

Exposures
- Tobacco smoking status: Current Smoker; Cigarettes per day: 20; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01877-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -15 days; Initial weight: 219 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01877-24: Section location: Anterior endometrium; Percent tumor nuclei: 80; Percent necrosis: 2.
- Sample C3N-01877-14: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -15 days; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01877-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -14 days; Method of sample procurement: Blood Draw.
